Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XZ, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XZ-01A (Primary Tumor).

[page 1 of 2]
Sex:F

Pathology Report

Accession Number:
Type: Surgical Pathology
Specimen Type: Soft tissue mass or simple excision
Procedure Date:
Ordering Provider:

Report Status: Final

CASE:

PATIENT: ~~REDACTED~~

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

A. IVC TUMOR, RESECTION:

LEIOMYOSARCOMA OF THE INFERIOR VENA CAVA, HIGH GRADE (9 cm).
Mitoses number up to 39 per 10 HPF.
Tumor necrosis is present (approximately 10%).
Tumor invades into the lumen of the vena cava.
Vena caval and soft tissue resection margins are negative for tumor.
Tumor is 0.3 cm from the inferior caval margin, 0.8 cm from the superior caval margin, and 0.1 cm from the soft tissue margin.
Adrenal gland is uninvolved.

B. RIGHT KIDNEY:

Kidney with no tumor present.
The kidney will be evaluated by _____ and the findings
will be reported in an addendum.

CLINICAL DATA:

History: Retroperitoneal tumor, leiomyosarcoma by outside biopsy (under review) and no previous treatment.
Operation: Resection of tumor, infrahepatic IVC, right nephroadrenalectomy.
Operative Findings: None given.
Clinical Diagnosis: Preop: Sarcoma. Postop: Sarcoma.

TISSUE SUBMITTED:

A/1. IVC tumor,
B/2. Right kidney.

GROSS DESCRIPTION:

The specimen consists of two parts; each was received fresh, labeled with the patient's name and unit number.

Part A, "IVC tumor", and consists of a 9.0 x 5.4 x 3.9 cm mass with a cuff of IVC (4.0 x 2.6 cm) and an intraluminal component/tumor thrombus (4.3 x 3.5 x 2.2 cm). The specimen was oriented in the frozen section room by

The specimen was further reviewed before fixation with
The entire surface of the mass was inked black and representative sections were sent for cytogenetics and taken for tissue bank. The mass is fleshy tan/white with one slightly hemorrhagic eccentric nodule (1.7 cm in diameter). Inferior to the mass is adrenal gland measuring 1.7 x 2.0 cm. There is one edge which was designated as "part of the right renal vein" by
The tumor does not appear to grossly extend beyond its pseudocapsule. Of note, the tumor penetrating the vena cava (thrombus) is located 0.8 cm from the superior vena caval resection margin, 0.3 cm from the inferior vena caval resection margin, 1.0 cm from the anterior resection margin, and 2.7 cm from the posterior (right renal vein) resection margin.

Micro A1-A2: Superior vena cava resection margin, perpendicular sections, 1 frag each,
Micro A3-A4: Inferior vena cava resection margin, perpendicular sections, 1 frag each,
Micro A5-A6: "Anterior" resection margin, perpendicular sections,

ICD-0-3

Leiomyosarcoma NOS 8890/3
Site: Inferior vena cava
C49.4
JW 5/15/14

[page 2 of 2]
Sex: r

Pathology Report

Micro A6-A8: Renal vein resection margin, 1 frag each, (Note: The eccentric nodule underlying the vena cava is submitted in A7).

Micro A9-A10: Eccentric nodule, 1 frag each,

Micro A11-A14: Representative sections of the mass, 1 frag each,

Micro A15: Mass and adrenal gland, 1 frag,

Micro A16-A17: Representative sections of tumor thrombus, 1 frag each,

Part B, "#2. Right kidney", and consists of an 11.5 x 6.0 x 4.0 cm nephrectomy specimen with perirenal fat (5.5 x 12.0 x 1.0 cm). There is a 1.2 cm renal vein, 1.0 cm renal artery, and an 8.0 cm ureter. The organ is serially sectioned to reveal homogeneous renal parenchyma without gross abnormalities.

Micro B1: Renal artery, renal vein, ureter margin, 3 frags,

Micro B2-B5: Renal cortex and medulla, 1 frag each,

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

, Electronically signed on

Source: NCI Genomic Data Commons file c0d8e646-707a-4270-b5b9-9247ff7a233b (TCGA-WK-A8XZ.B0322FA6-E7EB-4D8E-A310-CC1A77B52377.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).